Surgical pathology report (de-identified scan), TCGA case TCGA-HD-7831, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-7831-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Right hemiglossectomy, with frozen section:

Moderately differentiated squamous cell carcinoma, invasive to depth of 3 cm extending to the inked deep margin.

Definite angiolymphatic invasion is not identified.

The posterior margin is greater than 2 cm from the tumor.

The medial margin is 0.5 cm from the tumor (measured from the glass slide).

New deep margin, with OR consultation:

No tumor identified.

Level 1b:

Submandibular gland with no evidence of metastatic carcinoma.

Level 1a:

Metastatic squamous cell carcinoma in one (1) of the three (3) lymph nodes.

The carcinoma is intranodal and measures approximately 0.2 mm in greatest dimension.

Level 2a lymph nodes:

Metastatic squamous cell carcinoma in one (1) of nine (9) lymph nodes.

The tumor is intranodal and measures approximately 0.5 cm in greatest dimension.

Level 3 nodes:

Metastatic squamous cell carcinoma in one (1) of nine (9) lymph nodes.

The tumor is intranodal and measures approximately 0.5 cm in greatest dimension.

AJCC pathologic stage T2,N2.

Clinical Information

Right tongue squamous cell carcinoma.

[page 2 of 2]
Frozen Section Diagnosis

history: Tongue cancer.

Specimens: 1) Right hemiglossectomy
2) New deep margin

Gross: 1) Right hemiglossectomy measuring 7.1 x 4.0 x 3.0 cm. Deep margin is inked black and medial margin inked blue. Specimen is sectioned revealing a tan-white firm tumor measuring 3.0x 2.7 x 1.7 cm. The tumor grossly abuts the deep margin and is grossly located 2 mm from the medial margin. Representative sections of the margins are submitted as follows (all perpendicular): FSA1&A2 = deep margin; FSA3 and A4 = medial.
2) Portion of tissue with one surface designated as the new margin by the surgeon. The true new deep margin is inked black.

Frozen Section Diagnosis

Right hemiglossectomy (FSA1-A4):

Deep margin focally involved by carcinoma.

Medial margin free of tumor on frozen section

Gross Description

Received are frozen section control tissue specimens labeled "FSA1", "FSA2", "FSA3", and "FSA4". All tissue is submitted.

"NFA." The specimen consists of a hemiglossectomy measuring 7.1 x 4 x 3 cm. The deep surgical margin has been previously inked black and the medial margin blue. The specimen has been partially sectioned and there is a tan-white firm tumor measuring 3 x 2.7 x 1.7 cm. The tumor abuts the deep surgical margin. On the surface of the tongue on the deep lateral aspect, there is an ill-defined white mildly nodular area measuring 2 x 0.5 cm. "A1-3," additional sections of tumor with deep surgical margin; "A4-5," representative sections with medial surgical margin; "A6," representative section posterior deep surgical margin.

"B." The specimen consists of a soft brown fragment of tissue measuring 2 x 1 x 0.5 cm. The new true deep margin has been previously inked black. The specimen is submitted in toto in "B".

"C, Level 1B." The specimen consists of a 14 gram, 5 x 3 x 1.7 cm brown-tan encapsulated lobulated fragment of soft tissue. The cut surface is brown-tan and lobulated. No cysts or masses are noted. "C1-2," representative.

"D, Level 1A." The specimen consists of a 3.4 x 1.5 x 1.5 cm fragment of fat with three lymph nodes recovered, the largest measuring 0.8 cm. The cut surfaces are tan to white. "D," 3p, representative.

"E, Right Level 2A." The specimen consists of an irregular fragment of fat and soft connective tissue measuring 5 cm in greatest dimension. On sectioning, nine possible lymph nodes are recovered having tan to solid white cut surfaces. The largest lymph node measures 2 cm. "E1-2," representative.

"F, Level 3." The specimen consists of a 3.5 x 2 x 1.5 cm fragment of fat. On sectioning, nine possible lymph nodes are recovered ranging from tan to white and firm. The largest lymph node measures 0.9 cm in greatest dimension. "F1-2," representative

Source: NCI Genomic Data Commons file 99905fbe-13fc-4420-b4e5-daa82318f7a5 (TCGA-HD-7831.F160663A-FCD6-4880-B93D-EF20EBC5214B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).